Somatic mutation profile of tumor specimen TCGA-24-1436-01A (aliquot TCGA-24-1436-01A-01W-0549-09) from TCGA case TCGA-24-1436, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.2 years (20,881 days).
Specimen TCGA-24-1436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a58dd21e-2d38-47bc-a44b-7fe82ddb1eb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1436-10A (Blood Derived Normal), aliquot TCGA-24-1436-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8959ed1-0da0-4a02-b0e6-be63cd0ba98c

The open-access MAF lists 84 somatic variants for this specimen: 61 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 19, Nonsense Mutation 4, Frame Shift Del 3, Intron 3, Splice Site 2, In Frame Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SERPINC1 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 111/401 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121909550, CM890019, COSV62928911; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+1G>C p.X331_splice | Splice Site (SNP) | VAF 210/280 reads (75%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.2399T>C p.L800P | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55585962; called by muse, mutect2, varscan2
- ABLIM3 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750466880, COSV100448296; called by muse, mutect2
- ADCY8 | c.3026G>A p.R1009H | Missense Mutation (SNP) | VAF 114/2514 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53902127; called by muse, mutect2
- ANO8 | c.2955G>C p.Q985H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV50173404, COSV99344192; called by muse, mutect2, varscan2
- ATP10A | c.2881T>A p.S961T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.099); catalogued as COSV100791520; called by mutect2, varscan2
- BAG5 | c.576G>T p.E192D | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV54570225; called by muse, mutect2, varscan2
- C5orf22 | c.641C>G p.T214S | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV57597511; called by muse, mutect2, varscan2
- CACNA1G | c.2560C>T p.Q854* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100662529; called by muse, mutect2, varscan2
- CACNG1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs921123953, COSV99871780; called by muse, mutect2, varscan2
- CCDC40 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 6/165 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs1186248208, COSV53899256, COSV99482201; called by muse, mutect2
- CDC5L | c.1873del p.S625Pfs*5 | Frame Shift Del (DEL) | VAF 107/332 reads (32%) | catalogued as COSV65175352; called by mutect2, pindel, varscan2
- CLMP | c.558C>T p.D186= | Splice Region (SNP) | VAF 97/319 reads (30%) | catalogued as COSV71649306; called by muse, mutect2, varscan2
- CNTN5 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 4/80 reads (5%) | catalogued as COSV99681149, COSV99682550; called by muse, mutect2
- FLG2 | c.4932G>T p.R1644S | Missense Mutation (SNP) | VAF 35/1231 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1462607488, COSV101166072; called by muse, mutect2
- GPLD1 | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs745397779, COSV57754530; called by muse, mutect2, varscan2
- GSTK1 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1394011858, COSV100621840; called by muse, mutect2, varscan2
- GTF3C5 | c.1485_1496del p.E496_E499del | In Frame Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs762898069; called by mutect2, varscan2
- HJURP | c.1301T>C p.I434T | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1339567746, COSV64978631; called by muse, mutect2
- KIAA1755 | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1474434377, COSV54074157; called by muse, mutect2, varscan2
- KRT20 | c.33C>A p.S11R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV99391593; called by muse, mutect2
- KRTAP5-3 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 185/469 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV68790517; called by muse, mutect2, varscan2
- LAMB2 | c.4877G>C p.R1626P | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs752674803, COSV59731108, COSV59731439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LILRB4 | c.1162A>T p.K388* (on ENST00000391733 / NM_001278428.3; = p.K387* on NM_001278426.3) | Nonsense Mutation (SNP) | VAF 72/335 reads (21%) | catalogued as COSV54403649; called by muse, mutect2, varscan2
- MDN1 | c.6872C>T p.S2291L | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs114056139; called by muse, varscan2
- MLXIP | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV59834122; called by muse, mutect2, varscan2
- MOK | c.770A>C p.Q257P | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV51963409; called by muse, mutect2, varscan2
- MYH2 | c.3517del p.R1173Gfs*26 | Frame Shift Del (DEL) | VAF 74/264 reads (28%) | catalogued as COSV55434229; called by mutect2, pindel, varscan2
- NEB | c.17299G>A p.E5767K | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99427831; called by muse, mutect2
- NLRP3 | c.2749C>G p.L917V | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.633); catalogued as COSV60220589; called by muse, mutect2, varscan2
- NOTCH4 | c.2526+1G>A p.X842_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100901003; called by muse, mutect2, varscan2
- NUP210L | c.3647G>T p.W1216L | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55142253; called by muse, mutect2, varscan2
- PAPPA2 | c.3077A>G p.D1026G | Missense Mutation (SNP) | VAF 183/860 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV62791386; called by muse, mutect2, varscan2
- PATZ1 | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768984900, COSV53228788; called by muse, mutect2, varscan2
- PIWIL3 | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV100177281; called by muse, mutect2
- PSMA7 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1418350994, COSV99444763; called by muse, mutect2, varscan2
- SEMA4D | c.687C>A p.D229E | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100358784; called by muse, mutect2, varscan2
- SIGLEC12 | c.1289T>C p.V430A (on ENST00000291707 / NM_053003.4; = p.V312A on NM_033329.2) | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52459606; called by muse, mutect2, varscan2
- SLC22A11 | c.1253C>A p.A418D | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV57254513; called by mutect2, varscan2
- SMC1A | c.2693T>G p.L898R | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100447672; called by muse, varscan2
- SPRY2 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV65701222; called by muse, mutect2, varscan2
- SVIL | c.4834A>T p.T1612S (on ENST00000355867 / NM_021738.3; = p.T1186S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV63440247; called by muse, mutect2, varscan2
- SYCP3 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99901778; called by muse, mutect2, varscan2
- SYTL1 | c.1518G>C p.Q506H (on ENST00000543823; = p.Q494H on NM_032872.3) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.852); catalogued as COSV100539593; called by muse, mutect2
- TANC1 | c.3490C>T p.L1164F | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs751315989, COSV99715159; called by muse, mutect2, varscan2
- TAS2R50 | c.8C>G p.T3S | Missense Mutation (SNP) | VAF 101/357 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV67852967; called by muse, mutect2, varscan2
- TENM1 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 79/504 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV64448854; called by muse, mutect2, varscan2
- THSD4 | c.2500T>G p.C834G | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55962224; called by muse, mutect2, varscan2
- TICRR | c.4799G>A p.S1600N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.229); catalogued as COSV99179887; called by muse, mutect2, varscan2
- TRIM23 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 101/179 reads (56%) | catalogued as rs766787623, COSV51549720; called by muse, mutect2, varscan2
- TRPM3 | c.1979G>T p.W660L (on ENST00000357533 / NM_001366142.2; = p.W503L on NM_020952.6) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100678681; called by mutect2, varscan2
- TSHZ2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 30/453 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV100296743; called by muse, mutect2
- UAP1 | c.1499A>G p.D500G (on ENST00000271469 / NM_001324116.1; = p.D483G on NM_003115.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54849234; called by muse, mutect2, varscan2
- WASHC2A | c.3060G>C p.Q1020H | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99254782; called by muse, mutect2, varscan2
- ZBTB32 | c.1312C>A p.P438T | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV52889557; called by muse, mutect2, varscan2
- ZNF521 | c.2500G>C p.V834L | Missense Mutation (SNP) | VAF 47/1418 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV100833355; called by muse, mutect2
- ZNF615 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 74/361 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65032154; called by muse, mutect2, varscan2
- ZNF71 | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV100046283; called by mutect2, varscan2
- MKI67 | c.5871C>G p.F1957L | Missense Mutation (SNP) | VAF 20/683 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.545); called by muse, mutect2
- RC3H2 | c.1718del p.N573Ifs*11 | Frame Shift Del (DEL) | VAF 74/874 reads (8%) | called by mutect2, pindel
- AHNAK2 | c.15360G>T p.L5120= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100318896; called by muse, varscan2
- CASP14 | c.324C>T p.L108= | Silent (SNP) | VAF 24/391 reads (6%) | called by muse, mutect2
- CPA6 | c.1122G>A p.T374= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs747623971, COSV52721513; called by muse, mutect2, varscan2
- CSMD1 | c.6942A>T p.P2314= (on ENST00000520002; = p.P2313= on NM_033225.6) | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV59286542; called by muse, mutect2, varscan2
- ELP2 | c.1758T>C p.C586= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as COSV100627076; called by muse, mutect2
- GLCE | c.1062G>T p.L354= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as COSV55944430, COSV55945976; called by muse, mutect2, varscan2
- JAK1 | c.2397G>A p.L799= | Silent (SNP) | VAF 61/369 reads (17%) | catalogued as COSV100692380; called by muse, mutect2, varscan2
- MIER1 | c.72A>G p.P24= (on ENST00000355356 / NM_001077701.3; = p.P41= on NM_020948.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 254/497 reads (51%) | catalogued as COSV62529252, COSV62530121; called by muse, mutect2, varscan2
- OR13D1 | c.921G>A p.G307= | Silent (SNP) | VAF 48/218 reads (22%) | catalogued as rs1048026416, COSV59513533; called by muse, mutect2, varscan2
- OS9 | c.1635C>A p.V545= | Silent (SNP) | VAF 87/408 reads (21%) | catalogued as rs751053871, COSV57782049; called by muse, mutect2, varscan2
- PCDH11X | c.1197C>T p.F399= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV100015130; called by muse, mutect2, varscan2
- PIK3C3 | c.1425C>A p.L475= | Silent (SNP) | VAF 53/129 reads (41%) | catalogued as COSV56276204; called by muse, mutect2, varscan2
- PLD1 | c.2664A>G p.L888= | Silent (SNP) | VAF 78/680 reads (11%) | catalogued as COSV60565712; called by muse, mutect2, varscan2
- POFUT2 | c.1236C>T p.C412= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs980517133, COSV100499411; called by muse, mutect2, varscan2
- PRDM7 | c.747G>A p.G249= | Silent (SNP) | VAF 72/182 reads (40%) | catalogued as rs1425626884, COSV57986121; called by muse, varscan2
- SGCZ | c.804T>A p.S268= | Silent (SNP) | VAF 132/189 reads (70%) | catalogued as COSV65998274; called by muse, mutect2, varscan2
- SLIT2 | c.4299G>A p.Q1433= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV56561589; called by muse, mutect2, varscan2
- WNK3 | c.1905G>A p.K635= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV100672090; called by muse, mutect2
- ZNF595 | c.21G>A p.R7= | Silent (SNP) | VAF 33/556 reads (6%) | catalogued as COSV100227888, COSV59548836; called by muse, mutect2
- DCLK1 | c.1035+3732C>T | Intron (SNP) | VAF 82/225 reads (36%) | catalogued as rs748084859, COSV55173765; called by muse, mutect2, varscan2
- DPF3 | c.871+3069G>A | Intron (SNP) | VAF 22/110 reads (20%) | catalogued as COSV100818686; called by muse, mutect2, varscan2
- MIR376C | n.5G>C | RNA (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.61-455G>A | Intron (SNP) | VAF 74/529 reads (14%) | catalogued as rs758922924, COSV56597878; called by muse, mutect2, varscan2
